Somatic mutation profile of tumor specimen TCGA-RW-A68G-01A (aliquot TCGA-RW-A68G-01A-11D-A35D-08) from TCGA case TCGA-RW-A68G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 49.2 years (17,959 days).
Specimen TCGA-RW-A68G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a1da34-2495-4981-9e69-0f630bef441e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68G-10A (Blood Derived Normal), aliquot TCGA-RW-A68G-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392b4e97-4709-471e-8c63-4fbbb4d018c3

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSN1 | c.929_933del p.T310Mfs*49 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- NBEA | c.1526T>C p.L509S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOMO1 | c.2686T>C p.S896P | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSPAN13 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
